MMRF case MMRF_1403 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/05ba7768-7d72-4194-91ac-982e57a8b03d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.7 years (22,895 days); ISS stage: II; Days to last known disease status: 1,457 days (4.0 years); Days to last follow up: 1,457 days (4.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 231 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days; Days to treatment end: 925 days (2.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 932 days (2.6 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 944 days (2.6 years); Days to treatment end: 944 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 0): M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 25.2 mg/dL; Immunoglobulin G 77.1 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 4.6 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 11.8 g/dL; Glucose 4.18 mmol/L; C-Reactive Protein 0.04 mg/dL.
- Day 91 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 5.74 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 313 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 5.34 mmol/L.
- Day 176 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 3.61 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 5.2 g/dL; Glucose 5.06 mmol/L.
- Day 263 (ECOG 0): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.49 mg/dL; Immunoglobulin G 4.61 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 4.29 mmol/L.
- Day 343 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 7.11 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 3.41 mmol/L.
- Day 455 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 8.78 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 4.24 mmol/L.
- Day 540 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 8.69 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 3.19 mmol/L.
- Day 624 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 8.81 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.67 mmol/L.
- Day 736 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 9.51 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.9 mmol/L.
- Day 820 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 903 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 17 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 1,015 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 5.89 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 6.22 mmol/L.
- Day 1,100 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 7.83 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 4.07 mmol/L.
- Day 1,191 (ECOG 1): M Protein 0.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.6 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 6.16 mmol/L.
- Day 1,282 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.7 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 1.8 ×10⁹/L; Absolute Neutrophil 0.5 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 3.3 mmol/L.
- Day 1,373 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.7 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 1.6 ×10⁹/L; Absolute Neutrophil 0.5 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 4.62 mmol/L.
- Day 1,457 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 3.52 mmol/L.

Other clinical attributes
- Day -9: Weight: 78 kg; Height: 171 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1403_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1403_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
